Gene-level copy-number profile of tumor specimen ALCH-B1NQ-TTP1-A from ALCHEMIST case ALCH-B1NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.0 years (17,539 days).
Specimen ALCH-B1NQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83727f24-fcf7-42a8-93a1-54a41daf2036.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1NQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/a8709d36-502c-4bcb-8c42-44d9c2744678

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 301; copy number 1: 11,250; copy number 2: 30,258; copy number 3: 15,201; copy number 4: 1,871; copy number 5: 8; copy number 6: 11; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 280 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:181,668,749–181,669,028, 1 gene (within-gene range 0–3): Metazoa_SRP.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:18,667,249–18,667,370, 1 gene: CR383656.3.
- chr16:425,649–2,209,453, 166 genes (within-gene range 0–1) (broad region; genes not listed).
- chr19:489,176–2,051,244, 111 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 8: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr9:40,883,634–40,883,763, 1 gene, copy number 5: AL353626.2.
- chr9:136,206,333–136,245,812, 1 gene, copy number 5: QSOX2.
- chr11:48,880,111–48,908,946, 4 genes, copy number 6: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,706,832–54,725,816, 2 genes, copy number 5: OR4A5, OR4A6P.
- chr11:55,602,360–55,666,195, 4 genes, copy number 5: OR4C11, OR4P4, OR4S2, OR4C6.
- chr16:30,948,386–30,957,199, 3 genes, copy number 6 (within-gene range 2–6): AC135048.1, ORAI3, AC135048.3.
- chr18:20,946,906–21,111,813, 1 gene, copy number 6 (within-gene range 3–6): ROCK1.
- chr19:43,211,791–43,269,530, 2 genes, copy number 6: CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 8,430. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
